CGCI case BLGSP-71-19-00125 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8357007c-51a4-48fc-ae13-7c0b814b79dd

Demographics
Sex at birth: male; Race: white; Age at index: 16 years.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Classification of tumor: primary; Age at diagnosis: 16.3 years (5,951 days); Year of diagnosis: 2003; Method of diagnosis: Bone Marrow Aspirate; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,616 days (9.9 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Bone marrow; Sites of involvement: Bone marrow / Cerebrospinal fluid / Peripheral nervous system.
   Pathology details: Bone marrow malignant cells: Yes.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 3,616 days (9.9 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (Flow Cytometry): Positive; Specialized molecular test: CD10 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (Flow Cytometry): Positive.
- CD20 (IHC): Positive.
- CD3 (Flow Cytometry): Negative.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- Epstein-Barr Virus: Positive.
- Lactate Dehydrogenase 11030 [Blood test normal range upper: 770].

Other clinical attributes
- Day 0: Weight: 68 kg; Height: 177 cm; BMI: 21.7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-19-00125-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-19-00125-09A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Bone Marrow Aspirate; Tissue collection type: Retrospective.
  Slide BLGSP-71-19-00125-09A-01-S1-WG: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 60.
- Sample BLGSP-71-19-00125-16A: Sample type: Mononuclear Cells from Bone Marrow Normal; Tissue type: Normal; Specimen type: Mononuclear Cells from Bone Marrow; Preservation method: Frozen; Days to sample procurement: 350 days; Method of sample procurement: Bone Marrow Aspirate; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: Yes; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt leukemia/lymphoma -ALL, L3; Extranodal site involvement: 3; Extranodal involvment other: 7th cranial nerve; Lymph nodes examined: No; Bone marrow sample histology: Concordant Histology.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 11030; Immunophenotypic analysis method: Flow cytometry, not otherwise specified.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD3.
- Follow-up form: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
